Somatic mutation profile of tumor specimen TARGET-10-PATGWP-09A (aliquot TARGET-10-PATGWP-09A-01D) from TARGET case TARGET-10-PATGWP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.2 years (5,192 days).
Specimen TARGET-10-PATGWP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d6a17af-0067-4d8e-9cb9-ad7bae634d43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATGWP-10A (Blood Derived Normal), aliquot TARGET-10-PATGWP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9fd9223-b205-4184-b8d3-f2c9f500249c

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 2, Silent 2, Intron 2, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894366, CM061081, CM070967, CM070968, COSV55580791, COSV55588721, COSV56171292; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2443G>A p.V815I (on ENST00000404938 / NM_001163941.2; = p.V370I on NM_178559.6) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs558132589, COSV51723996; called by muse, varscan2
- DHX15 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61028395; called by muse, mutect2, varscan2
- KRT77 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs529823573, COSV59242035; called by muse, mutect2, varscan2
- MFSD14B | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV64702380; called by muse, mutect2, varscan2
- NOTCH1 | c.4754T>G p.L1585R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, varscan2
- PKNOX2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as COSV53557677; called by muse, mutect2, varscan2
- TGIF2LX | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.889); catalogued as rs763760276, COSV52215133, COSV99383481; called by muse, mutect2, varscan2
- TRIM5 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760714681, COSV59902725; called by muse, mutect2, varscan2
- TSPAN12 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV56082541; called by muse, mutect2, varscan2
- NFAT5 | c.3337C>T p.Q1113* | Nonsense Mutation (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- NOTCH1 | c.7508_7511dup p.P2505Gfs*3 | Frame Shift Ins (INS) | VAF 20/42 reads (48%) | called by mutect2, varscan2
- ADCY9 | c.1896G>A p.S632= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs564832517, COSV53573869; called by muse, mutect2, varscan2
- PTCH1 | c.3375C>T p.P1125= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as rs369760318, CD043423; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRE3 | chr19:14674935 ins TGGGACC | 5'Flank (INS) | VAF 20/43 reads (47%) | called by mutect2, pindel, varscan2
- MAN2C1 | c.422+847C>T | Intron (SNP) | VAF 21/36 reads (58%) | catalogued as rs934026391; called by muse, mutect2, varscan2
- NDC80 | c.*44T>C | 3'UTR (SNP) | VAF 5/12 reads (42%) | catalogued as rs1249304525; called by muse, mutect2
- VPS26B | c.722-92C>T | Intron (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
